TCGA case TCGA-69-7761 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - Cleveland Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/77828a90-8e2a-4664-b674-d837e6e34fe4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 84 years; Vital status: Alive.

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 85.0 years (31,041 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Pemetrexed Disodium; Treatment intent type: Adjuvant; Days to treatment start: 84 days; Days to treatment end: 147 days; Number of cycles: 4; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 186 days; Disease response: Tumor Free.
- ECOG performance status: 1; Timepoint: Other.

Molecular and laboratory tests
- EGFR mutation, nos: Positive.

Other clinical attributes
- DLCO (% of predicted): 80; FEV1/FVC before bronchodilator (%): 91; FEV1 before bronchodilator (% of reference): 98.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 20; Tobacco smoking onset year: 1955; Tobacco smoking quit year: 1975.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-69-7761-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-69-7761-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 40.
  Slide TCGA-69-7761-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 30.
- Sample TCGA-69-7761-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-69-7761-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Acinar Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Lower; Location lung parenchyma: Peripheral Lung; EGFR mutation status: Yes; Pulmonary function test indicator: Yes.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Alimta.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form: New tumor event diagnosis indicator: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 186 days; disease-specific survival: no event (censored), 186 days; progression-free interval: no event (censored), 186 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-69-7761-01A-11D-2166-01): tumor purity 0.23, ploidy 3.68, whole-genome doublings 1.
